Somatic mutation profile of tumor specimen ALCH-B27P-TTP1-A (aliquot ALCH-B27P-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B27P, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.5 years (27,211 days).
Specimen ALCH-B27P-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f52b61ef-af49-4fae-b7ac-c15e9626d9a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B27P-NB1-A (Blood Derived Normal), aliquot ALCH-B27P-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19c2e6be-e7fb-48ce-9fc6-36598e107c4c

The open-access MAF lists 43 somatic variants for this specimen: 30 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 9, RNA 1, Frame Shift Del 1, 3'Flank 1, Splice Region 1, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADSS1 | c.296-7C>G | Splice Region (SNP) | VAF 9/161 reads (6%) | catalogued as rs932631035; called by muse, mutect2
- CDH9 | c.570C>G p.N190K | Missense Mutation (SNP) | VAF 13/267 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as COSV99151415; called by muse, mutect2
- DPPA4 | c.571A>G p.T191A | Missense Mutation (SNP) | VAF 25/405 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as rs1341137824, COSV100169567; called by muse, mutect2
- EBF1 | c.1538C>A p.S513Y | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); catalogued as COSV100565670, COSV58176675; called by muse, mutect2
- FAT3 | c.9340C>A p.Q3114K | Missense Mutation (SNP) | VAF 17/333 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV53152906; called by muse, mutect2
- FBLN1 | c.1055C>A p.T352K | Missense Mutation (SNP) | VAF 23/390 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV53045235; called by muse, mutect2
- ICAM3 | c.981T>A p.H327Q | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99348856; called by mutect2, varscan2
- INHBA | c.833G>T p.G278V | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV54221694; called by muse, mutect2, varscan2
- MIPEP | c.1424C>T p.P475L | Missense Mutation (SNP) | VAF 20/312 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as COSV66299676; called by muse, mutect2
- PCDH15 | c.3406G>T p.D1136Y | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57372502, COSV57380811, COSV57404150; called by muse, mutect2
- SH3RF2 | c.857G>T p.R286L | Missense Mutation (SNP) | VAF 14/237 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.048); catalogued as rs771899314; called by muse, mutect2
- ZNF469 | c.7261C>T p.R2421C (on ENST00000437464; = p.R2449C on NM_001367624.2) | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as rs1308314699; called by muse, mutect2
- ADAMTSL2 | c.1874G>T p.R625M | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AMY2B | c.679G>T p.D227Y | Missense Mutation (SNP) | VAF 27/610 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); called by muse, mutect2
- CD79B | c.386C>A p.T129N | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.005); called by muse, mutect2
- COL6A5 | c.3064G>T p.V1022L | Missense Mutation (SNP) | VAF 16/346 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.173); called by muse, mutect2
- DENND3 | c.442T>C p.F148L | Missense Mutation (SNP) | VAF 15/374 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- EFNA1 | c.65C>T p.T22I | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, mutect2
- GRINA | c.985_1000del p.Q329Tfs*6 | Frame Shift Del (DEL) | VAF 14/134 reads (10%) | called by mutect2, pindel
- ITGAM | c.2588C>G p.T863S (on ENST00000648685 / NM_001145808.2; = p.T862S on NM_000632.4) | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT tolerated (0.89); PolyPhen benign (0.007); called by muse, mutect2
- KIF15 | c.29G>T p.R10L | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.247); called by muse, mutect2
- KLHL40 | c.770T>C p.V257A | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.387); called by muse, mutect2
- L2HGDH | c.1327G>T p.A443S | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LAMA1 | c.2107G>A p.A703T | Missense Mutation (SNP) | VAF 25/322 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- PDS5B | c.871C>G p.Q291E | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT tolerated (0.95); PolyPhen benign (0.115); called by muse, mutect2
- PLA2G10 | c.393G>T p.K131N | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.249); called by muse, mutect2
- SOD2 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); called by muse, mutect2
- SP4 | c.485G>T p.S162I | Missense Mutation (SNP) | VAF 18/201 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2
- VPS13A | c.5281C>G p.L1761V | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- ZNF226 | c.1201A>T p.S401C | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); called by muse, mutect2
- AFF4 | c.2256T>G p.A752= | Silent (SNP) | VAF 10/140 reads (7%) | called by muse, mutect2
- C6orf132 | c.2223T>C p.T741= | Silent (SNP) | VAF 7/93 reads (8%) | called by muse, mutect2
- CHRND | c.177A>T p.T59= | Silent (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- FREM3 | c.3780C>A p.I1260= | Silent (SNP) | VAF 18/227 reads (8%) | called by muse, mutect2
- H2BC11 | c.117C>T p.S39= | Silent (SNP) | VAF 21/340 reads (6%) | catalogued as rs751383107, COSV60362411; called by muse, mutect2
- INHA | c.744G>T p.L248= | Silent (SNP) | VAF 22/272 reads (8%) | catalogued as COSV99217782; called by muse, mutect2
- MYO1A | c.984G>A p.K328= | Silent (SNP) | VAF 54/626 reads (9%) | catalogued as rs371875751; called by muse, mutect2
- PIWIL3 | c.1737G>C p.V579= | Silent (SNP) | VAF 10/162 reads (6%) | catalogued as COSV59994520; called by muse, mutect2
- SLC9A1 | c.273C>G p.V91= | Silent (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- EPSTI1 | chr13:42888375 T>C | 3'Flank (SNP) | VAF 36/510 reads (7%) | catalogued as rs1239574581; called by muse, mutect2
- KCTD19 | c.3+51G>A | Intron (SNP) | VAF 15/125 reads (12%) | catalogued as rs1208600210; called by muse, mutect2
- MIR1302-3 | n.17T>C | RNA (SNP) | VAF 38/950 reads (4%) | catalogued as rs1350185947; called by muse, mutect2
- RNA5-8SP2 | chr16:34158686 G>A | 5'Flank (SNP) | VAF 8/165 reads (5%) | called by muse, mutect2
